Gene-level copy-number profile of tumor specimen C3L-09184-03 from CPTAC case C3L-09184, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 54.2 years (19,785 days).
Specimen C3L-09184-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 29e9f76c-c4e3-4e84-b1a3-4af64e133aa9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09184-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/cc6ffcea-7a33-4346-8964-15037fe6622d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 583; copy number 1: 4,679; copy number 2: 19,392; copy number 3: 23,367; copy number 4: 5,982; copy number 5: 3,311; copy number 6: 1,264; copy number 7: 164; copy number 8: 11; copy number 9: 16; copy number 12: 8; copy number 13: 5; copy number 14: 2; copy number 17: 52; copy number 18: 6; copy number 22: 3; copy number 23: 23; copy number 24: 3; copy number 25: 5; copy number 28: 2; copy number 88: 2; copy number 113: 16; copy number 122: 1.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,160,235–22,214,672, 49 genes: Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:23,500,691–26,118,408, 16 genes: AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2, AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr9:64,637,845–64,765,535, 4 genes: AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr17:18,476,737–18,494,945, 1 gene: LGALS9C.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 319 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:56,647,988–56,710,614, 3 genes, copy number 12: HOPX, AC108215.1, RPL17P20.
- chr4:56,977,722–58,118,070, 15 genes, copy number 14–122 (within-gene range 2–122): POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, SRIP1, AC096725.1.
- chr9:32,727,069–34,252,523, 67 genes, copy number 9–22 (within-gene range 5–22) (broad region; genes not listed).
- chr15:32,765,544–33,194,714, 1 gene, copy number 18 (within-gene range 4–18): FMN1.
- chr15:32,970,727–34,671,095, 40 genes, copy number 12–28: AC018515.1, HNRNPA1P71, AC019278.1, TMCO5B, AC055874.1, RYR3, Y_RNA, AC010809.3, AC010809.2, AC010809.1, AVEN, CHRM5, AC009268.2, AC009268.3, AC009268.1, EMC7, AC079203.1, PGBD4, KATNBL1, EMC4, SLC12A6, AC079203.2, Y_RNA, NOP10, NUTM1, LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252.
- chr16:33,577,502–33,875,468, 13 genes, copy number 8–9 (within-gene range 5–9): AC142384.1, BMS1P8, ENPP7P13, AC136428.2, IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3.
- chr17:39,566,915–39,877,896, 16 genes, copy number 113: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr18:20,946,906–21,120,506, 3 genes, copy number 7: ROCK1, AC022795.1, RNU6-120P.
- chr19:15,338,948–18,098,944, 161 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
